Somatic mutation profile of tumor specimen TCGA-N5-A59E-01A (aliquot TCGA-N5-A59E-01A-11D-A28R-08) from TCGA case TCGA-N5-A59E, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Myometrium; FIGO stage: Stage IVB; Age at diagnosis: 62.0 years (22,650 days).
Specimen TCGA-N5-A59E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0910ead-d183-4fb8-9484-2acad3caba24.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N5-A59E-10A (Blood Derived Normal), aliquot TCGA-N5-A59E-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85b88162-20df-43c3-8459-33aed3e4dba3

The open-access MAF lists 69 somatic variants for this specimen: 52 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 16, Frame Shift Del 6, In Frame Del 2, Nonsense Mutation 2, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPP2R1A | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 15/65 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs786205228, CM153573, COSV59042232, COSV59042841; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659A>C p.Y220S | Missense Mutation (SNP) | VAF 30/34 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- C3AR1 | c.1119del p.S373Rfs*41 | Frame Shift Del (DEL) | VAF 57/119 reads (48%) | catalogued as COSV50818313, COSV50821795; called by mutect2, pindel, varscan2
- CCDC66 | c.1511G>T p.R504L (on ENST00000394672 / NM_001353147.1; = p.R470L on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as COSV58309738; called by muse, mutect2, varscan2
- CFAP46 | c.7135G>C p.E2379Q | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.391); catalogued as COSV54157802; called by muse, mutect2
- CSMD2 | c.9470G>A p.R3157H | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs753503294, COSV53881918; called by muse, mutect2, varscan2
- GRM7 | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as rs1025403472, COSV100735833, COSV63173475, COSV99066173; called by muse, mutect2, varscan2
- KDM2B | c.1240G>A p.A414T | Missense Mutation (SNP) | VAF 29/33 reads (88%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs781933591; called by muse, mutect2, varscan2
- KLK2 | c.678C>G p.I226M | Missense Mutation (SNP) | VAF 55/160 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57570751; called by muse, mutect2, varscan2
- KRTAP5-5 | c.181G>A p.G61S | Missense Mutation (SNP) | VAF 100/136 reads (74%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs1167185109, COSV68785274; called by muse, varscan2
- LIN7A | c.299G>T p.S100I | Missense Mutation (SNP) | VAF 18/18 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV54022306; called by muse, mutect2
- MMEL1 | c.637G>C p.E213Q | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs559978146; called by muse, mutect2, varscan2
- NARF | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.158); catalogued as rs760628241, COSV59111870; called by muse, mutect2, varscan2
- PRDM11 | c.176C>G p.T59R (on ENST00000530656 / NM_001359633.1; = p.T25R on NM_001256695.1) | Missense Mutation (SNP) | VAF 33/40 reads (83%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.999); catalogued as rs770286632; called by muse, mutect2, varscan2
- RANBP2 | c.8890A>G p.T2964A | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.54); PolyPhen benign (0.055); catalogued as rs1392315376; called by muse, mutect2, varscan2
- SLAMF6 | c.145_147del p.K49del | In Frame Del (DEL) | VAF 91/267 reads (34%) | catalogued as rs766689319; called by mutect2, pindel, varscan2
- TNFRSF14 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.449); catalogued as rs201844409, COSV63186435; called by muse, mutect2, varscan2
- TRPM8 | c.366C>A p.C122* | Nonsense Mutation (SNP) | VAF 55/86 reads (64%) | catalogued as rs745885016, COSV61224203; called by muse, mutect2, varscan2
- ZXDB | c.1337G>A p.R446Q | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100886066; called by muse, mutect2, varscan2
- ABCD2 | c.767C>A p.P256H | Missense Mutation (SNP) | VAF 56/108 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADGRG4 | c.8056G>A p.A2686T | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- ANO2 | c.2235G>C p.M745I (on ENST00000356134 / NM_001278597.3; = p.M749I on NM_001278596.3) | Missense Mutation (SNP) | VAF 19/255 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2
- ARSJ | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 150/166 reads (90%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- BPIFC | c.342C>G p.I114M | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2
- BTBD17 | c.1082C>T p.S361L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.26); called by muse, mutect2
- CRTC2 | c.506C>T p.T169I | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CTSE | c.173_174dup p.C60Pfs*105 (on ENST00000360218; = p.C60Pfs*100 on NM_001910.4) | Frame Shift Ins (INS) | VAF 32/112 reads (29%) | called by mutect2, pindel, varscan2
- CYP1A2 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCP1A | c.1738C>A p.H580N | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- ERBB3 | c.2275C>T p.H759Y | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM71D | c.436G>C p.G146R | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FPR2 | c.838A>T p.I280F | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- FRMD3 | c.892del p.W298Gfs*72 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | called by mutect2, varscan2
- GPR15 | c.383G>A p.S128N | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IPO8 | c.458T>A p.L153Q | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- IRAG1 | c.1699_1701del p.E567del | In Frame Del (DEL) | VAF 40/56 reads (71%) | called by pindel, varscan2
- MAGIX | c.792G>C p.K264N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MSMO1 | c.11A>G p.N4S | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MTHFD2L | c.460G>C p.D154H (on ENST00000395759 / NM_001144978.2; = p.D96H on NM_001004346.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NRXN2 | c.2796_2800del p.T933Pfs*18 | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel
- OR4C12 | c.676A>C p.N226H | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIK3C3 | c.717C>G p.D239E | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- PKHD1 | c.4652C>A p.S1551* | Nonsense Mutation (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.677_698+1del | Frame Shift Del (DEL) | VAF 9/96 reads (9%) | called by mutect2, pindel
- PXDNL | c.3464A>T p.D1155V | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- RLIM | c.1297T>G p.S433A | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT tolerated (0.15); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SAMHD1 | c.905C>G p.S302C | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- SUSD4 | c.1364del p.P455Lfs*8 | Frame Shift Del (DEL) | VAF 13/122 reads (11%) | called by mutect2, varscan2
- TANC1 | c.1616_1640del p.R539Nfs*6 | Frame Shift Del (DEL) | VAF 38/157 reads (24%) | called by mutect2, pindel
- TNKS | c.2138A>C p.K713T | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- TRIM33 | c.620G>C p.S207T | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.205); called by mutect2, varscan2
- ZBTB3 | c.937G>C p.D313H | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP13A3 | c.57T>C p.I19= | Silent (SNP) | VAF 14/123 reads (11%) | called by muse, mutect2, varscan2
- BRD1 | c.1330C>T p.L444= | Silent (SNP) | VAF 52/173 reads (30%) | called by muse, mutect2, varscan2
- BRD1 | c.1329C>A p.V443= | Silent (SNP) | VAF 52/175 reads (30%) | called by muse, mutect2, varscan2
- CAPZB | c.171G>A p.K57= | Silent (SNP) | VAF 21/48 reads (44%) | called by muse, mutect2, varscan2
- CEP131 | c.462G>A p.P154= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as rs781565082; called by muse, mutect2, varscan2
- GPRC5A | c.453A>G p.E151= | Silent (SNP) | VAF 209/342 reads (61%) | catalogued as rs1361721470; called by muse, mutect2, varscan2
- H2AC4 | c.234C>T p.R78= | Silent (SNP) | VAF 35/144 reads (24%) | catalogued as rs370267838; called by muse, mutect2, varscan2
- ITGAD | c.2949C>A p.V983= | Silent (SNP) | VAF 116/166 reads (70%) | called by muse, mutect2, varscan2
- KCNT2 | c.927G>A p.L309= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV54083742; called by muse, mutect2, varscan2
- LIMK2 | c.627G>A p.G209= | Silent (SNP) | VAF 29/126 reads (23%) | called by muse, mutect2, varscan2
- NUP93 | c.243G>T p.L81= | Silent (SNP) | VAF 11/52 reads (21%) | called by muse, mutect2, varscan2
- POLR3D | c.825C>G p.L275= | Silent (SNP) | VAF 9/58 reads (16%) | called by muse, mutect2, varscan2
- PTPRF | c.3897G>C p.S1299= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV63448434; called by mutect2, varscan2
- SLC8A1 | c.1278C>T p.A426= | Silent (SNP) | VAF 11/132 reads (8%) | catalogued as COSV60487254; called by muse, mutect2
- SSTR4 | c.840G>C p.L280= | Silent (SNP) | VAF 20/152 reads (13%) | catalogued as rs759002787, COSV54800241; called by muse, mutect2, varscan2
- TMTC4 | c.1800C>T p.H600= (on ENST00000376234 / NM_001350577.2; = p.H619= on NM_032813.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as rs201076381; called by muse, mutect2
- EGFL7 | c.572-267G>C | Intron (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
